Gene-level copy-number profile of tumor specimen TCGA-AN-A0AT-01A from TCGA case TCGA-AN-A0AT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.4 years (22,798 days).
Specimen TCGA-AN-A0AT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.170030ae-72f3-46cc-b82a-d23c7f3ad70d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0AT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90bc50d5-414d-462c-878f-cf0b3399e974

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 207; copy number 2: 17,771; copy number 3: 4,509; copy number 4: 29,585; copy number 5: 1,970; copy number 6: 4,196; copy number 7: 820; copy number 8: 462; copy number 9: 27; copy number 10: 39; copy number 11: 123; copy number 13: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0AT-01A-11D-A036-01): tumor purity 0.64, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 207 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–4,994,972, 65 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:20,999,509–29,318,952, 115 genes (broad region; genes not listed).
- chr10:87,751,512–87,863,533, 4 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr17:30,968,785–31,538,211, 22 genes: AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 279 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:43,230,836–44,244,384, 19 genes, copy number 11–13 (within-gene range 6–13): THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1, RN7SKP66, DYNC2LI1, ABCG5, ABCG8, LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B.
- chr5:151,595,264–152,726,160, 18 genes, copy number 10 (within-gene range 5–10): AC011374.3, AC011374.1, SPARC, CLMAT3, RN7SKP232, AC011374.2, ATOX1, AC091982.1, RPLP1P6, AC091982.3, G3BP1, GLRA1, AC091982.2, RNA5SP198, LINC01933, AC008571.2, NMUR2, AC008571.1.
- chr6:11,414,636–14,136,918, 40 genes, copy number 11: AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83.
- chr6:20,534,457–21,232,404, 1 gene, copy number 10 (within-gene range 7–10): CDKAL1.
- chr6:20,993,474–22,654,455, 15 genes, copy number 10 (within-gene range 8–10): RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL.
- chr6:36,940,071–38,154,624, 27 genes, copy number 9 (within-gene range 6–9): AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr7:63,011,463–66,031,544, 149 genes, copy number 11–13 (broad region; genes not listed).
- chr8:127,253,213–127,482,139, 5 genes, copy number 10 (within-gene range 4–10): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr19:34,593,329–34,675,699, 4 genes, copy number 13 (within-gene range 4–13): SCGB2B2, AC020910.4, AC020910.1, AC020910.2.
- chr19:34,645,662–34,646,070, 1 gene, copy number 13: SCGB2B3P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
